Surgical pathology report (de-identified scan), TCGA case TCGA-O2-A52S, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CALGB, specimen TCGA-O2-A52S-01A (Primary Tumor).

[page 1 of 3]
Patient: .

Surg Path

CLINICAL HISTORY:
Lung mass.

GROSS EXAMINATION:

- A. "Left minor carina biopsy", received is a frozen section remnant labeled AF1 which is submitted entirely in block A1.
- B. "2R lymph node", received for frozen section and placed in formalin is a remnant labeled BF1 which is submitted entirely in block B1.
- C. "4L lymph node", received for frozen section analysis is a frozen section remnant labeled CF1 which is submitted entirely in block C1.
- D. "2L lymph node", received for frozen section analysis is a frozen section remnant labeled DF1 which is submitted entirely in block D1.
- E. "Level #7 lymph node", received is a frozen section remnant labeled EF1 which is submitted entirely in block E1.
- F. "4R lymph node", received is a frozen section remnant labeled FF1 which is submitted entirely in block F1.
- G. "Left lower lobectomy", received for frozen section analysis and placed in formalin is a lobectomy specimen (post fixation weight 278 gm, measuring 15.5 x 12.2 x 7.5 cm). The specimen is serially sectioned to reveal a 3.4 x 3 x 2.7 cm white-tan firm, ill-defined nodule which abuts the main bronchus and is seen to protrude through the bronchus at the hilum. In closest proximity this mass appears to abut but does not appear to invade through the pleural surface. The remaining lung parenchyma appears consolidated and thickened in the subpleural region an ill-defined area measuring approximately 3.7 x 2.5 cm. No other abnormalities are identified.

BLOCK SUMMARY:

- G1- mass with respect to lobar bronchus
G2- mass with respect to pleura (VVG prospectively requested)
G3-4 area of pleural thickening
G5-6 representative of lung parenchyma
G7- representative of mass
G8- hilar lymph node and vascular margin

Also received are two frozen section remnants labeled GF1 and GF2 which are submitted entirely in block G9-10 respectively.

- H. "Final bronchial margin", received is a frozen section remnant labeled HF1 which is submitted entirely in block H1.
- I. "Level 9 lymph node", received is a yellow-tan fragment of fibrofatty tissue which measure 1.3 x 1 x 0.6 cm. The specimen is serially sectioned and submitted entirely in block I1.
- J. "Level 8 lymph node", received fresh and placed in formalin is a yellow-tan fragment of fibrofatty tissue which measures 1.9 x 1 x 0.5 cm. The specimen is serially sectioned and submitted entirely in block J1.
- K. "Level 7 lymph node #2", received fresh and placed in formalin are three yellow-tan fragments of fibrofatty tissue, the largest of which measures 2.1 x 1.2 x 1 cm. The largest lymph node is submitted in blocks K1-3, two smaller

1CD-0-3
Carver - splenome cell, pos 8070/3
Sgt. Lung, @m/160 234.3 km
11/14/12

[page 2 of 3]
lymph nodes are submitted in block K4.

L. "Level 11 lymph node", received is are three yellow-tan fragments of fibrofatty tissue which measure an aggregate of 1.7 x 1.1 x 0.4 cm. The specimen is submitted entirely in block L1.

INTRA OPERATIVE CONSULTATION:

- A. "Left minor carina biopsy": AFI- negative
- B. "2R lymph node": BFI- negative, one lymph node
- C. "4L lymph node": CFI- negative, one lymph node
- D. "2L lymph node": DFI- negative, lymph node
- E. "Level 7 lymph node": EFI- negative, one LN
- F. "4R lymph node": FFI- negative, one lymph node
- G. "Left lower lobectomy": GF1- (tangential bronchial margin) positive for carcinoma
GF2- (tangential atrial margin)- negative
- H. "Final bronchial margin": HFI- negative

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: LEFT LOWER LOBECTOMY, MEDIASTINAL LYMPH NODE BIOPSIES

PATHOLOGIC STAGE (AJCC 6th Edition): pT4 pN2 pMx ✓

NOTE: Information on pathology stage and the operative procedure is transmitted to this institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

- A. "LEFT MINOR CARINA BIOPSY":

FRAGMENTS OF BRONCHIAL TISSUE, NO EVIDENCE OF MALIGNANCY.

- B. "2R LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

- C. "4L" (LYMPH NODE BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

- D. "2L LYMPH NOD" (LYMPH NODE BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

- E. "LEVEL 7 LYMPH NODE" (LYMPH NODE BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

- F. "4R LYMPH NODE" (LYMPH NODE BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

[page 3 of 3]
G. "LEFT LOWER LOBECTOMY" (LOBECTOMY):

CARCINOMA OF LUNG:

Histologic type: SQUAMOUS CELL.
Histologic grade: POORLY DIFFERENTIATED

Extent of invasion

- Max. tumor diameter: 3.4 CM
- Mainstem bronchus: NEGATIVE
- Visceral pleura: POSITIVE
- Chest wall: NEGATIVE
- Mediastinum: POSITIVE
- >1 tumor nodules? NEGATIVE
- Panlobar atelectasis? NEGATIVE

Margins

- Bronchial: POSITIVE, FINAL MARGIN REPORTED SEPARATELY.
- Vascular: NEGATIVE
- Parenchymal: NEGATIVE
- Pleural: NEGATIVE

Other prognostic features

- Vascular invasion: PRESENT

Regional lymph nodes: METASTATIC SQUAMOUS CELL CARCINOMA IDENTIFIED IN ONE OF THREE PERIBRONCHIAL LYMPH NODES.

Additional findings: POST OBSTRUCTIVE ORGANIZING PNEUMONIA AND BRONCHIECTASIS.

H. "FINAL BRONCHIAL MARGIN" (BIOPSY):

SEGMENT OF BRONCHUS, NO EVIDENCE OF MALIGNANCY.

I. "LEVEL 9 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

J. "LEVEL 5 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

K. "LEVEL 7 LYMPH NODE NUMBER TWO" (LYMPH NODE BIOPSY):

METASTATIC SQUAMOUS CELL CARCINOMA PRESENT IN TWO LYMPH NODES.

L. "LEVEL 11 LYMPH NODE" (BIOPSY):

METASTATIC SQUAMOUS CELL CARCINOMA PRESENT IN LYMPH NODE.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Electronically signed.

Diagnostic Discrepancy		✓
Histologic Discrepancy		✓
Review/Initials	11/9/12	11/12/12

Source: NCI Genomic Data Commons file 371667d0-bf09-42af-8191-bc780dd011e5 (TCGA-O2-A52S.A5404A41-95B6-4290-A240-EAD96CD4B691.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).